CCDI case PBCNGN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/c63491f2-0184-4d5e-a51c-8045a814d641

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 4.0 years (1,472 days).

Biospecimens (3 samples)
- Sample 0DVZ0O: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DVZ10, 0DVZ1K (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
